Gene-level copy-number profile of tumor specimen TCGA-KN-8428-01A from TCGA case TCGA-KN-8428, project TCGA-KICH (Kidney Chromophobe). Sex at birth: male; Vital status: Dead; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 71.9 years (26,252 days).
Specimen TCGA-KN-8428-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-KICH.96c81f73-0399-4e44-9da1-a8d149912d5f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-KN-8428-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/83310d6e-ea49-4d71-aa58-29d6e8e35e13

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 16; copy number 1: 5,500; copy number 2: 17,576; copy number 3: 17,277; copy number 4: 16,332; copy number 5: 3,114.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-KN-8428-01A-11D-2308-01): tumor purity 0.78, ploidy 2.85, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 16 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:44,712–942,743, 16 genes: AL713922.1, TUBB8, IL9RP2, ZMYND11, AL713922.2, RNA5SP297, DIP2C, RNA5SP298, RN7SL754P, AL669841.1, AL358216.1, MIR5699, PRR26, AL157709.1, LARP4B, AL359878.2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 5,500. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
